CPTAC case C3N-01349 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cefebaa2-f118-40ef-8a54-7608691ebf6f

Demographics
Sex at birth: female; Race: white; Year of birth: 1939; Vital status: Dead; Days to death: 555 days (1.5 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 77.3 years (28,217 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 555 days (1.5 years); Days to last follow up: 850 days (2.3 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 5 cm; Lymph node involvement: Positive; Lymph nodes positive: 6; Lymph nodes tested: 6; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 405 days (1.1 years); Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 850 days (2.3 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 405 days (1.1 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 86 kg; Height: 165 cm; BMI: 31; Hormonal contraceptive use: Never Used.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01349-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 123 mg.
- Sample C3N-01349-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Initial weight: 218 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01349-22: Section location: Anterior endometrium; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-01349-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -15 days; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01349-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -13 days; Method of sample procurement: Blood Draw.
